Somatic mutation profile of tumor specimen 0DFJKR from CCDI case PBBKTT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.7 years (4,623 days).
Specimen 0DFJKR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a133fa2-b681-4c82-a23c-7377ea5a13ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFJJ5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d47ba579-01b4-42ec-b71f-7a9b5c603e51

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Intron 4, Nonsense Mutation 3, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 120/270 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 138/286 reads (48%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, varscan2
- BTBD1 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.12); catalogued as rs765497456; called by muse, varscan2
- CAND2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as rs375037359; called by muse, varscan2
- CELSR3 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770332399, COSV51126063; called by muse, varscan2
- CSMD1 | c.4660G>A p.A1554T (on ENST00000520002; = p.A1553T on NM_033225.6) | Missense Mutation (SNP) | VAF 213/380 reads (56%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); catalogued as rs562244069; called by muse, varscan2
- DCAF4L2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs755701425, COSV60476952, COSV60481637; called by muse, varscan2
- DDX3X | c.668C>T p.A223V (on ENST00000399959; = p.A224V on NM_001356.5) | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67863799; called by muse, varscan2
- H6PD | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 204/490 reads (42%) | catalogued as rs774520385, COSV66230390; called by muse, varscan2
- HMCN2 | c.13472C>T p.T4491M | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs962505782, COSV70933852; called by muse, varscan2
- KCP | c.4228C>T p.R1410* (on ENST00000620378; = p.R1534* on NM_001366122.1) | Nonsense Mutation (SNP) | VAF 98/250 reads (39%) | catalogued as rs370254255; called by muse, varscan2
- KMT2D | c.12626C>T p.P4209L | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as rs765983115, COSV99981807; ClinVar: uncertain significance; called by muse, varscan2
- TBL3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 150/363 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs372224239; called by muse, varscan2
- UVRAG | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs768673283, COSV100638385; called by muse, varscan2
- ADGRL3 | c.473G>T p.R158I (on ENST00000506720 / NM_001322402.2; = p.R90I on NM_015236.6) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CFAP47 | c.4015A>G p.T1339A | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.09); called by muse, varscan2
- COG5 | c.350T>A p.I117K | Missense Mutation (SNP) | VAF 183/401 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, varscan2
- DCBLD1 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 168/186 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, varscan2
- FH | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.414); called by muse, varscan2
- KMT2D | c.15626G>T p.G5209V | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SOS1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 154/395 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, varscan2
- KCTD19 | c.1032C>T p.S344= | Silent (SNP) | VAF 153/334 reads (46%) | catalogued as rs777176067, COSV58575433; called by muse, varscan2
- MMACHC | c.747C>T p.D249= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as COSV53113781; called by muse, varscan2
- PAPPA2 | c.915C>T p.I305= | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as rs1404266012; called by muse, varscan2
- PLEKHM3 | c.2043G>A p.G681= | Silent (SNP) | VAF 159/317 reads (50%) | called by muse, varscan2
- ELF2 | c.-70C>A | 5'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, varscan2
- GMFB | c.357+80A>G | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- MZB1 | c.*59C>T | 3'UTR (SNP) | VAF 98/225 reads (44%) | catalogued as rs960413797; called by muse, varscan2
- NFATC1 | c.1959+87G>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs879204500, COSV53709036; called by muse, varscan2
- RPS16 | c.247+21G>A | Intron (SNP) | VAF 52/102 reads (51%) | catalogued as rs373056723; called by muse, varscan2
- VARS2 | c.2038-44A>G | Intron (SNP) | VAF 3/19 reads (16%) | called by muse, varscan2
